Somatic mutation profile of tumor specimen C3N-04119-02 (aliquot CPT0237910007) from CPTAC case C3N-04119, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.3 years (19,826 days).
Specimen C3N-04119-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de4161da-bb2e-469d-a85a-44314aa2fc1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04119-31 (Blood Derived Normal), aliquot CPT0237960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13ca3d29-661c-44d7-84fd-4a6343692b7f

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Nonsense Mutation 8, Splice Site 2, 5'UTR 1, 3'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/339 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 87/735 reads (12%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3292C>T p.Q1098* | Nonsense Mutation (SNP) | VAF 64/757 reads (8%) | catalogued as COSV61372190; called by muse, mutect2
- CADPS | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 53/623 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1214963810, COSV99337214; called by muse, mutect2
- CDKN2A | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 90/868 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58729783; called by muse, mutect2, varscan2
- CFAP46 | c.3044C>T p.T1015M | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs898358192; called by muse, mutect2, varscan2
- COL22A1 | c.2646G>A p.P882= | Splice Region (SNP) | VAF 61/415 reads (15%) | catalogued as rs756859195, COSV57346815; called by muse, mutect2, varscan2
- DNAH5 | c.5816C>T p.A1939V | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs376871205; called by muse, mutect2
- EEF2K | c.1232-1G>C p.X411_splice | Splice Site (SNP) | VAF 44/490 reads (9%) | catalogued as COSV99533736; called by muse, mutect2
- ESPL1 | c.4168C>T p.R1390C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs149944800; called by mutect2, varscan2
- FBN3 | c.2588C>T p.T863M | Missense Mutation (SNP) | VAF 36/530 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139953945; called by muse, mutect2
- HYAL2 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 56/606 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1472320415, COSV63306114; called by muse, mutect2
- ITGAX | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs377108919; called by muse, mutect2, varscan2
- MAGEB17 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1444091046; called by muse, mutect2, varscan2
- MYOT | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 36/391 reads (9%) | catalogued as COSV99295896; called by muse, mutect2
- RASGRF2 | c.2455C>T p.R819* | Nonsense Mutation (SNP) | VAF 30/208 reads (14%) | catalogued as rs1162038901, COSV54122570; called by muse, varscan2
- RICTOR | c.3058A>G p.S1020G | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs757720947; called by muse, mutect2
- SEMA5B | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs555943228, COSV52093968; called by muse, mutect2
- SLC35F3 | c.640G>A p.A214T (on ENST00000366617 / NM_001300845.1; = p.A283T on NM_173508.4) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762720695, COSV100784683; called by muse, mutect2, varscan2
- SLC49A3 | c.1204C>T p.R402* (on ENST00000404286 / NM_001294341.2; = p.R401* on NM_032219.4) | Nonsense Mutation (SNP) | VAF 50/367 reads (14%) | catalogued as rs772057703; called by muse, mutect2, varscan2
- SLFN11 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1224767096; called by muse, mutect2, varscan2
- SMAD4 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 70/591 reads (12%) | catalogued as COSV61693823; called by muse, mutect2, varscan2
- SYNE1 | c.6014G>A p.R2005Q (on ENST00000367255 / NM_182961.4; = p.R2012Q on NM_033071.3) | Missense Mutation (SNP) | VAF 46/449 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55065581; called by muse, mutect2, varscan2
- TMEM178A | c.378C>A p.D126E | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.242); catalogued as COSV56143161; called by muse, mutect2, varscan2
- TMEM59 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755400755; called by muse, varscan2
- TRANK1 | c.7436G>A p.R2479Q | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); catalogued as rs756325744, COSV57145305; called by muse, mutect2
- WFDC10A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | catalogued as rs1314989558, COSV100385741, COSV58096465; called by muse, mutect2
- ACTL10 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2
- KLF4 | c.1333A>T p.R445W | Missense Mutation (SNP) | VAF 43/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- LMBR1 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2
- OR5D18 | c.165A>T p.K55N | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2
- PABPC4 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 39/441 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); called by muse, mutect2
- PCDHGB4 | c.2156C>G p.P719R | Missense Mutation (SNP) | VAF 60/564 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PDCD11 | c.2896G>T p.D966Y | Missense Mutation (SNP) | VAF 62/718 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- RAB21 | c.220-2A>C p.X74_splice | Splice Site (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- RELA | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCLY | c.621G>C p.E207D (on ENST00000651534; = p.E199D on NM_016510.7) | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SP100 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2
- UGT2A1 | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- WNT3A | c.653G>A p.W218* | Nonsense Mutation (SNP) | VAF 42/439 reads (10%) | called by muse, mutect2, varscan2
- AHDC1 | c.873C>T p.L291= | Silent (SNP) | VAF 35/296 reads (12%) | catalogued as rs758776352; called by muse, mutect2, varscan2
- CSH1 | c.468C>T p.D156= | Silent (SNP) | VAF 82/854 reads (10%) | catalogued as rs369347327; called by muse, mutect2, varscan2
- KLHDC7B | c.960G>T p.A320= (on ENST00000395676; = p.A961= on NM_138433.5) | Silent (SNP) | VAF 39/380 reads (10%) | catalogued as COSV67464840; called by muse, mutect2, varscan2
- LPCAT1 | c.1110G>A p.A370= | Silent (SNP) | VAF 61/593 reads (10%) | catalogued as rs756860780, COSV99358646; called by muse, mutect2, varscan2
- MMP24 | c.354C>T p.Y118= | Silent (SNP) | VAF 57/525 reads (11%) | catalogued as rs201429856; called by muse, mutect2, varscan2
- NLGN2 | c.2193C>T p.A731= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs775547220; called by muse, mutect2, varscan2
- POSTN | c.1446C>T p.N482= | Silent (SNP) | VAF 26/390 reads (7%) | catalogued as rs147888983; called by muse, mutect2
- SLC25A48 | c.72C>T p.H24= | Silent (SNP) | VAF 29/382 reads (8%) | called by muse, mutect2
- SYTL1 | c.1335C>T p.Y445= (on ENST00000543823; = p.Y433= on NM_032872.3) | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as rs1390161243; called by muse, mutect2, varscan2
- TIAM1 | c.1440C>T p.D480= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs745535556, COSV54545301; called by muse, mutect2, varscan2
- YTHDF1 | c.1074T>C p.S358= | Silent (SNP) | VAF 64/593 reads (11%) | called by muse, mutect2, varscan2
- ZNF521 | c.3432C>T p.N1144= | Silent (SNP) | VAF 38/298 reads (13%) | catalogued as rs1011241462, COSV64130709; called by muse, mutect2, varscan2
- ELAVL4 | c.-25C>T | 5'UTR (SNP) | VAF 12/134 reads (9%) | catalogued as rs1392462125, COSV100836742; called by muse, mutect2
- SCYL2 | c.335+27T>G | Intron (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
- ZNF717 | chr3:75732068 G>A | 3'Flank (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
